Somatic mutation profile of tumor specimen 0D9DR6 from CCDI case PBBIJX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.6 years (1,324 days).
Specimen 0D9DR6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd058465-e982-4ebe-8b0d-b7b8ba691add.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9DR7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdf20f19-722e-4d17-a10a-bed4c2a81370

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC2A3 | c.950T>A p.I317N | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- CYFIP1 | c.747C>T p.Y249= | Silent (SNP) | VAF 27/472 reads (6%) | catalogued as rs764436554; called by muse, mutect2
- GCM1 | c.534C>T p.S178= | Silent (SNP) | VAF 16/547 reads (3%) | catalogued as rs1021595884, COSV52523065; called by muse, mutect2
- YTHDF1 | c.384G>A p.A128= | Silent (SNP) | VAF 126/396 reads (32%) | catalogued as rs746455610, COSV64832875; called by muse, varscan2
